Somatic mutation profile of tumor specimen 0DS0ZV from CCDI case PBCHCI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.4 years (3,437 days).
Specimen 0DS0ZV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 733e2b63-c97d-4540-bdb2-80c2d7b0216f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS0ZA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f862b338-a371-45e8-b1ab-12b0ec3e9fd1

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX41 | c.300G>A p.A100= | Splice Region (SNP) | VAF 115/328 reads (35%) | catalogued as COSV57905153; called by muse, mutect2, varscan2
- EZHIP | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 208/479 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs782700812; called by muse, mutect2, varscan2
- GNPTG | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 216/648 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as CM101200, CM163762; called by muse, mutect2, varscan2
- OR4D6 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 190/534 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs200132677; called by muse, mutect2, varscan2
- SLITRK4 | c.1892C>T p.T631M | Missense Mutation (SNP) | VAF 22/560 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs782534462, COSV62022405; called by muse, mutect2
- TMEM132B | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 43/670 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.241); catalogued as rs759184529, COSV54749863; called by muse, mutect2
- BTBD19 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 30/423 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2
- COL7A1 | c.7591C>A p.P2531T | Missense Mutation (SNP) | VAF 95/590 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.056); called by mutect2, varscan2
- STARD8 | c.2773_2776delinsTTT p.L925Ffs*122 | Frame Shift Del (DEL) | VAF 66/690 reads (10%) | called by pindel, varscan2*
- COL25A1 | c.*3A>C | 3'UTR (SNP) | VAF 108/421 reads (26%) | called by muse, mutect2
